Somatic mutation profile of tumor specimen TARGET-20-PARHVK-04A (aliquot TARGET-20-PARHVK-04A-01D) from TARGET case TARGET-20-PARHVK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.6 years (4,983 days).
Specimen TARGET-20-PARHVK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f861db37-aa92-4965-a5b6-478ae1bd2453.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHVK-14A (Bone Marrow Normal), aliquot TARGET-20-PARHVK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/717f3437-b874-476b-ab2e-b4bf90acaded

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Ins 2, Splice Site 1, Intron 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH9 | c.12076C>G p.L4026V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV52348234, COSV99309125; called by muse, mutect2, varscan2
- GSE1 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 35/77 reads (45%) | catalogued as COSV53671780; called by muse, mutect2, varscan2
- SETD2 | c.6361delinsGG p.R2121Gfs*6 | Frame Shift Ins (INS) | VAF 88/265 reads (33%) | catalogued as COSV57445272; called by mutect2*, pindel, varscan2*
- EZH2 | c.2181-1G>C p.X727_splice (on ENST00000460911 / NM_001203247.2; = p.X732_splice on NM_004456.5) | Splice Site (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- SETD2 | c.6362dup p.R2122Pfs*5 | Frame Shift Ins (INS) | VAF 145/191 reads (76%) | called by mutect2, varscan2
- FGFR1 | c.358+458G>A | Intron (SNP) | VAF 32/96 reads (33%) | catalogued as rs576807361; called by muse, mutect2, varscan2
